CCDI case PBCITS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/950744ba-f8fa-4b09-a7b0-9e70fe19e2d1

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.3 years (5,938 days).

Biospecimens (3 samples)
- Sample 0DVVIA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVVKI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVVLY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
